FM case AD5072 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS.
https://portal.gdc.cancer.gov/cases/5922d75f-b14b-4430-b377-435483a3c8b5

Female, 67.5 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the uterus; metastasis biopsied or resected from the bladder. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Metastatic.
